Surgical pathology report (de-identified scan), TCGA case TCGA-QQ-A8VG, project TCGA-SARC (Sarcoma), tissue source site Roswell Park, specimen TCGA-QQ-A8VG-01A (Primary Tumor).

[page 1 of 3]
Date of Surgery:

SPECIMEN(S): A. WLE MELANOMA RIGHT LOWER BACK

CLINICAL HISTORY:

None provided

ICD-O-3
Tumor, peripheral nerve sheath,
malignant 954013
Site: Trunk NOS 049.6
J 1/21/14

PRE-OPERATIVE DIAGNOSIS:

Melanoma/neurogenic tumor

GROSS DESCRIPTION:

A. WLE MELANOMA RIGHT LOWER BACK

Received fresh in single matching container and subsequently fixed in formalin, labeled "melanoma right back", is an wide excision specimen consisting of an ellipse of skin and underlying soft tissue. The specimen measures 21.3 cm x 10.1 cm and is excised to a variable depth of 2.0 cm medially to 5.0 cm laterally. A well healed scar is identified on the medial aspect of the skin surface measuring 5.2 cm in length, located 2.2 cm from the medial surgical margin. A firm mass is palpable through the length of the specimen in the soft tissue. The specimen is oriented by sutures as follows: a single suture marks the medial most margin, a double suture marks the cephalad (superior) margin and a triple suture marks the lateral margin. The specimen is inked as follows: deep margin: black, medial margin: green, lateral margin: red, cephalad (superior) margin: blue and the caudal (inferior) margin: orange. The specimen is serially sectioned perpendicular to its long axis to reveal a heterogeneous mass with alternating fleshy and fibrotic areas, located in the soft tissue. The medial aspect of this mass is located just deep to the healed surgical scar and is tan-pink, fleshy, measuring 3.5 cm x 3.5 cm x 2.2 cm in maximum dimensions. The fascia underlying the fleshy area is grossly negative for tumor and is located <0.1 cm from the fleshy area. Lateral to the fleshy area, the mass has a tan-white to pale yellow fibrotic appearance with an infiltrating edge. In the central part of the specimen, another fleshy, tan-pink, fairly well-circumscribed area is identified and measuring 2.5 x 1.9 x 2.2 cm, located approximately 0.2 cm from the deep fascial margin. Lateral to this area, the mass has a fibrotic, tan-white, infiltrative appearance. The medial, lateral, cephalad (superior) and caudal (inferior) surgical resection margins are grossly negative for tumor. The remainder of the soft tissue has a pale yellow, lobulated appearance with multiple interspersed fibrous septae. Digital images are taken. Representative sections from the specimen are submitted for microscopic examination as follows:

- A1-A3: perpendicular medial margin submitted en-face
- A4-A8: perpendicular supero-medial margin
- A9-A17: perpendicular superior margin, medial half
- A18-A25: perpendicular superior margin, lateral half
- A26-A32: perpendicular supero-lateral margin
- A33-A39: perpendicular infero-lateral margin
- A40-A55: perpendicular inferior margin, lateral half
- A56-A63: perpendicular inferior margin, medial half
- A64-A67: perpendicular infero-medial margin
- A68-A75: perpendicular deep margin underlying fleshy tumor mass (medial part of specimen)

[page 2 of 3]
Date of Surgery:

- A74-A75: tumor to closest deep margin
A76: fleshy tumor mass (closest to skin) underlying previous biopsy site
A77-A78: fleshy tumor mass deep to previous biopsy site
A79-A80: fibrotic area (lateral to medial fleshy area) to deep margin
A81-A82: fleshy area in center of specimen
A83-A84: fibrotic areas in lateral half of specimen
A85: representative uninvolved fat
A86-A88: additional tumor mass (closest to skin) underlying previous biopsy site

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block A76

Population: Tumor Cells

Stain/Marker:	Result:	Comment:
S-100	Positive	Strong
A103,MELAN-A	Negative	
HMB 45	Negative	
MICROPHTHALMIA	Negative	
CD57-LEU7	Positive	rare cells

Material: Block A78

Population: Tumor Cells

Stain/Marker:	Result:	Comment:
CD57-LEU7	Positive	

Material: Block A79

Population: Tumor Cells

Stain/Marker:	Result:	Comment:
S-100	Positive	
A103,MELAN-A	Negative	
HMB 45	Negative	
MICROPHTHALMIA	Negative	
CD57-LEU7	Positive	Numerous cells

Material: Block A81

Population: Tumor Cells

Stain/Marker:	Result:	Comment:
S-100	Positive	
A103,MELAN-A	Negative	
HMB 45	Negative	
MICROPHTHALMIA	Negative	
CD57-LEU7	Negative	Inflammatory cells positive

[page 3 of 3]
Date of Surgery:

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the

The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and negative controls.

DIAGNOSIS:

A. RIGHT LOWER BACK, WIDE LOCAL EXCISION:

- MALIGNANT PERIPHERAL NERVE SHEATH TUMOR (MPNST) ARISING IN ASSOCIATION WITH A DIFFUSE NEUROFIBROMA
- SURGICAL MARGINS NEGATIVE FOR MPNST
- SUPERIOR, INFERIOR, LATERAL AND MEDIAL SURGICAL MARGINS FOCALLY POSITIVE FOR NEUROFIBROMA

Comment: There is a diffuse neurofibroma involving much of the tissue in the resection specimen extending to the above captioned margins. In the region of the right paraspinous tissue discrete hypercellular nodular proliferation of fusiform to spindle cells is present associated with mitotic activity and cytologic pleomorphism. A prominent lymphocytic inflammatory cell infiltrate is present. No overlying intraepithelial melanocytic proliferation is identified.

The original biopsy material suggested a melanoma arising in association with a peripheral nerve sheath tumor. The findings in the resection specimen are more consistent with a focus of MPNST for arising within a pre-existing neurofibroma. The degree of S100 in her neck cavity would be unusual in MPNST however the other morphologic findings are most consistent with the above stated interpretation The MPNST is approximately 3 mm from the deep resection margin.

Source: NCI Genomic Data Commons file 2e7957c4-1f43-4e9d-80a6-d6b280fb3d59 (TCGA-QQ-A8VG.14E9C818-30C7-402D-A90F-1299FE9D6D15.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).